FM case AD13466 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Prostate gland.
https://portal.gdc.cancer.gov/cases/21d66749-3211-4d6c-995b-1d68f12e0f02

Male, 68.7 years: Carcinoma, undifferentiated, NOS (ICD-O-3 8020/3) of the prostate gland; primary biopsied or resected from the prostate gland. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
